TCGA case TCGA-DK-A3WW — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2ab0fb7b-ad2a-403d-9411-712974ccd878

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.4; Tissue or organ of origin: Posterior wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 57.2 years (20,909 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 633 days (1.7 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 47; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Gemcitabine + Paclitaxel; Days to treatment start: 127 days; Days to treatment end: 177 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 252 days; Disease response: Tumor Free.
- Days to follow up: 497 days (1.4 years); Disease response: Tumor Free.
- Days to follow up: 633 days (1.7 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 85 kg; Height: 186 cm; BMI: 24.6.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.
- Occupation type: Legal Professionals.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DK-A3WW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 880 mg.
  Slide TCGA-DK-A3WW-01A-02-TSB: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 8.
- Sample TCGA-DK-A3WW-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DK-A3WW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Occupation current: Attorney; Occupation primary: Attorney; Occupation primary chemical exposure: None Reported; Occupation primary industry: Legal field; Tobacco smoking history indicator: 1; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Papillary; Anatomic organ subdivision: Wall Posterior; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: No; Incidental prostate cancer indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Drug treatment 3: Pharmaceutical therapy drug name: Taxol.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 633 days; disease-specific survival: no event (censored), 633 days; disease-free interval: no event (censored), 633 days; progression-free interval: no event (censored), 633 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DK-A3WW-01A-22D-A23L-01): tumor purity 0.5, ploidy 2, whole-genome doublings 0.
